Somatic mutation profile of tumor specimen C3N-02439-02 (aliquot CPT0158660009) from CPTAC case C3N-02439, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 57.2 years (20,891 days).
Specimen C3N-02439-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aed1e414-c1f3-4238-9290-e8610c5546af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02439-32 (Blood Derived Normal), aliquot CPT0159410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd16f303-7544-4b1e-9040-78f9386f7a34

The open-access MAF lists 54 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Nonsense Mutation 6, Frame Shift Del 2, Intron 2, Splice Site 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PBRM1 | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | hotspot (GDC flag); catalogued as COSV56262126; called by muse, mutect2, varscan2
- CHD2 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 12/236 reads (5%) | catalogued as COSV67715954; called by muse, mutect2
- CRY1 | c.1255G>C p.G419R | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749074808; called by muse, mutect2, varscan2
- CUX2 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1239347097; called by muse, mutect2
- DNAH2 | c.5974C>T p.R1992C | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139075634; called by muse, mutect2, varscan2
- FLG | c.11947G>A p.D3983N | Missense Mutation (SNP) | VAF 129/1376 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as rs748281982, COSV64242953; called by muse, mutect2
- GRIA1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 64/988 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs759117420, COSV53589188; called by muse, mutect2
- H4C2 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 81/422 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs1255455743; called by muse, mutect2, varscan2
- LCMT1 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV66725884; called by muse, mutect2, varscan2
- PBRM1 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as COSV56269219; called by muse, mutect2, varscan2
- PGLYRP4 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs370456458; called by muse, mutect2, varscan2
- POU4F3 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 130/725 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57944627; called by muse, mutect2, varscan2
- PTGIS | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54835960, COSV99071890; called by muse, mutect2, varscan2
- RYR1 | c.730G>T p.V244F | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62087371; called by muse, mutect2
- SLC1A2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 73/388 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs766885690; called by muse, mutect2, varscan2
- ZFAND4 | c.1457C>A p.S486Y | Missense Mutation (SNP) | VAF 85/365 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1225890380; called by muse, mutect2, varscan2
- ANXA8 | c.364T>G p.S122A | Missense Mutation (SNP) | VAF 50/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATG7 | c.1784T>A p.L595* | Nonsense Mutation (SNP) | VAF 27/206 reads (13%) | called by muse, mutect2, varscan2
- CRAT | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- DBT | c.961C>G p.Q321E | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- FRG2C | c.195T>A p.N65K | Missense Mutation (SNP) | VAF 16/579 reads (3%) | SIFT tolerated (0.67); PolyPhen benign (0.046); called by muse, mutect2
- FRG2C | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 18/590 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); called by muse, mutect2
- GALM | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.603); called by muse, mutect2
- GNAQ | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.31); called by muse, mutect2
- IGF1 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 45/291 reads (15%) | called by muse, mutect2, varscan2
- KCNF1 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- MARCHF10 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 18/656 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- MLH3 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- MTMR10 | c.160T>C p.C54R | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO15B | c.8042C>T p.A2681V | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- NSUN5 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 57/341 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NT5C1B | c.710G>A p.R237H (on ENST00000359846 / NM_001199086.2; = p.R177H on NM_033253.4) | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- NUSAP1 | c.23A>G p.E8G | Missense Mutation (SNP) | VAF 52/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PFN3 | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 87/578 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PMS1 | c.132+1G>C p.X44_splice | Splice Site (SNP) | VAF 28/664 reads (4%) | called by muse, mutect2
- POMP | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 69/332 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- PRKAA2 | c.1530T>A p.H510Q | Missense Mutation (SNP) | VAF 133/505 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABGAP1L | c.922del p.T308Pfs*23 (on ENST00000489615 / NM_001243765.2; = p.T191Pfs*23 on NM_001243764.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, pindel
- TMEM67 | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ZNF107 | c.994_995del p.E332Mfs*6 | Frame Shift Del (DEL) | VAF 20/139 reads (14%) | called by mutect2, pindel, varscan2
- ZNF292 | c.341T>G p.L114* | Nonsense Mutation (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- ACSL1 | c.1279A>C p.R427= | Silent (SNP) | VAF 45/221 reads (20%) | called by muse, mutect2, varscan2
- BAIAP3 | c.2142G>A p.R714= | Silent (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- DEFB110 | c.123G>A p.T41= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as rs764651038; called by muse, mutect2
- ELFN1 | c.1755C>T p.G585= | Silent (SNP) | VAF 72/301 reads (24%) | catalogued as rs763883088, COSV70036447; called by muse, mutect2, varscan2
- HECTD2 | c.57C>G p.P19= | Silent (SNP) | VAF 39/245 reads (16%) | called by muse, mutect2, varscan2
- PTPRF | c.2580C>T p.A860= | Silent (SNP) | VAF 138/609 reads (23%) | catalogued as rs772134870, COSV63443497; called by muse, mutect2, varscan2
- RBM15 | c.558G>T p.V186= | Silent (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- SLC35G3 | c.612C>T p.S204= | Silent (SNP) | VAF 119/648 reads (18%) | called by muse, mutect2, varscan2
- SLIT3 | c.528C>T p.A176= | Silent (SNP) | VAF 48/347 reads (14%) | catalogued as COSV60612292; called by muse, mutect2, varscan2
- ADIG | c.*117T>A | 3'UTR (SNP) | VAF 36/130 reads (28%) | called by muse, mutect2
- AP000769.3 | chr11:65502079 A>G | 5'Flank (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- FOXP2 | c.1267-1540G>A | Intron (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- STON2 | c.2784+16A>G | Intron (SNP) | VAF 65/260 reads (25%) | called by muse, mutect2, varscan2
